FM case AD17313 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas.
https://portal.gdc.cancer.gov/cases/0bbe8b59-a47c-40c3-8a36-19e111995a71

Male, 77.4 years: Neuroendocrine carcinoma, NOS (ICD-O-3 8246/3); specimen biopsied or resected from the liver. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Tumor.
